Gene-level copy-number profile of tumor specimen TCGA-XE-AANK-01A from TCGA case TCGA-XE-AANK, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 22.4 years (8,176 days).
Specimen TCGA-XE-AANK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5b3ae145-a055-4263-a870-6830908dbd70.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AANK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/449c27ed-1e75-4789-856e-0c5e0e55832b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 512; copy number 3: 489; copy number 4: 25,863; copy number 5: 11,384; copy number 6: 14,638; copy number 7: 2,981; copy number 8: 1,282; copy number 9: 222; copy number 10: 254; copy number 11: 35; copy number 12: 126; copy number 13: 215; copy number 14: 64; copy number 15: 808; copy number 16: 30.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,754 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–32,428,131, 549 genes, copy number 9–15 (broad region; genes not listed).
- chr7:47,740,202–48,108,736, 8 genes, copy number 9: PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1.
- chr7:71,779,491–77,198,626, 168 genes, copy number 10–11 (within-gene range 6–11) (broad region; genes not listed).
- chr7:77,193,369–77,199,848, 1 gene, copy number 11 (within-gene range 6–11): FGL2.
- chr9:101,334,084–105,776,629, 61 genes, copy number 9 (broad region; genes not listed).
- chr9:110,190,048–112,881,671, 48 genes, copy number 9 (within-gene range 8–9): C9orf152, TXN, TXNDC8, SVEP1, RNU6-1039P, AL592463.1, MUSK, AL513328.1, LPAR1, RNU6-432P, Y_RNA, RNY4P18, AL162414.1, MIR7702, OR2K2, ECPAS, RNA5SP294, ZNF483, PTGR1, AL135787.1, LRRC37A5P, DNAJC25, DNAJC25-GNG10, GNG10, SHOC1, AL354877.1, RNU6-1013P, UGCG, MIR4668, RNU6-710P, AL138756.1, SUSD1, RNU6-855P, Y_RNA, AL158824.1, PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28, AL359073.1, HSDL2, C9orf147, KIAA1958, AL445187.1, INIP, AL390067.1, SNX30.
- chr9:120,244,979–123,268,586, 72 genes, copy number 9 (broad region; genes not listed).
- chr12:66,767–34,249,958, 831 genes, copy number 12–16 (broad region; genes not listed).
- chr14:18,333,726–18,602,129, 9 genes, copy number 9: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12.
- chr21:10,640,028–13,120,807, 7 genes, copy number 9: AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
